Somatic mutation profile of tumor specimen HCM-CSHL-0368-D37-31A (aliquot HCM-CSHL-0368-D37-31A-11D-A78T-36) from HCMI case HCM-CSHL-0368-D37, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Noninfiltrating intraductal papillary adenocarcinoma; Tissue or organ of origin: Gallbladder; AJCC pathologic stage: Stage 0; Tumor grade: GB; Age at diagnosis: 65.9 years (24,078 days).
Specimen HCM-CSHL-0368-D37-31A: Sample type: Neoplasms of Uncertain and Unknown Behavior; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f51369fd-88ab-483d-b696-5bcd1dc5b69c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0368-D37-10A (Blood Derived Normal), aliquot HCM-CSHL-0368-D37-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d80ae5b-2447-4332-ba6e-b73919971549

The open-access MAF lists 159 somatic variants for this specimen: 106 protein-altering or splice-affecting, 36 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 36, Nonsense Mutation 13, Intron 7, RNA 5, Frame Shift Del 3, 5'UTR 3, Splice Site 2, Frame Shift Ins 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.70C>T p.R24* | Nonsense Mutation (SNP) | VAF 57/211 reads (27%) | catalogued as rs145945630, CM086465, COSV57336675; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 132/401 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 313/401 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC011448.1 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52277079; called by muse, mutect2, varscan2
- ADAMTS3 | c.2617C>T p.R873C | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759621311, COSV54392009; called by muse, mutect2, varscan2
- ADGRL2 | c.902C>T p.T301M | Missense Mutation (SNP) | VAF 28/390 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770097166, COSV54649463; called by muse, mutect2
- ALPK2 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 96/263 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.038); catalogued as COSV64490263; called by muse, mutect2, varscan2
- ASPM | c.6852_6855del p.L2285Rfs*6 | Frame Shift Del (DEL) | VAF 43/165 reads (26%) | catalogued as rs587783259; called by mutect2, pindel, varscan2
- ATL3 | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 99/340 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.254); catalogued as rs781024290; called by muse, mutect2, varscan2
- B4GALNT4 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0.019); catalogued as COSV100327832; called by muse, mutect2, varscan2
- BCLAF1 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 14/64 reads (22%) | catalogued as rs759289578, COSV62145348; called by muse, mutect2, varscan2
- BCOR | c.867G>A p.W289* | Nonsense Mutation (SNP) | VAF 123/157 reads (78%) | catalogued as COSV60707678; called by muse, mutect2, varscan2
- BLOC1S5 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 241/336 reads (72%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.873); catalogued as rs1409220472; called by muse, mutect2, varscan2
- CADPS2 | c.3221G>A p.R1074H | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs181462771; called by muse, mutect2, varscan2
- CCNA2 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 74/230 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.771); catalogued as COSV52658301; called by muse, mutect2, varscan2
- CELSR1 | c.6262C>T p.R2088* | Nonsense Mutation (SNP) | VAF 37/139 reads (27%) | catalogued as COSV99419456; called by muse, mutect2, varscan2
- CHAF1A | c.2540C>T p.S847L | Missense Mutation (SNP) | VAF 116/241 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs749929809, COSV56670982; called by muse, mutect2, varscan2
- CHRM2 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 114/303 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748172206, COSV57765468, COSV57787501; called by muse, mutect2, varscan2
- CLEC14A | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 122/375 reads (33%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.547); catalogued as COSV60562785; called by muse, mutect2, varscan2
- CNPY3 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 76/206 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as rs963890660; called by muse, varscan2
- COL3A1 | c.3607G>A p.A1203T | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as rs550665335, CM1512473, COSV58595485, COSV58597783; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL8A1 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.656); catalogued as COSV99658570; called by muse, varscan2
- CPNE7 | c.1405G>A p.V469M | Missense Mutation (SNP) | VAF 63/221 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs368685442; called by muse, mutect2, varscan2
- CR1 | c.3799C>T p.H1267Y | Missense Mutation (SNP) | VAF 66/276 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); catalogued as COSV100887387; called by muse, mutect2, varscan2
- DUSP22 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 40/311 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as rs1204467799; called by muse, mutect2, varscan2
- EEF1A1 | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100303411, COSV58550679; called by muse, mutect2, varscan2
- ESR1 | c.832G>T p.G278C | Missense Mutation (SNP) | VAF 99/276 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.264); catalogued as COSV52790184; called by muse, mutect2, varscan2
- FBXO4 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 60/182 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs376695334; called by muse, mutect2, varscan2
- FLNC | c.6310G>A p.E2104K | Missense Mutation (SNP) | VAF 158/417 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs753069149; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GAA | c.1870C>T p.L624F | Missense Mutation (SNP) | VAF 154/597 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs764377962; called by muse, mutect2, varscan2
- GDI2 | c.1238C>T p.T413M | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1010582641; called by muse, mutect2, varscan2
- LAMA3 | c.3523G>A p.E1175K | Missense Mutation (SNP) | VAF 233/675 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs539451824, COSV58066561; called by muse, varscan2
- MAGEB6 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 52/74 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.152); catalogued as rs750400525, COSV66871849; called by muse, mutect2, varscan2
- MC3R | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 173/467 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.192); catalogued as rs767240745, COSV54762982; called by muse, mutect2, varscan2
- MYO18B | c.3659C>T p.P1220L | Missense Mutation (SNP) | VAF 173/472 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs780088091; called by muse, mutect2, varscan2
- OR10A2 | c.159A>C p.L53F | Missense Mutation (SNP) | VAF 120/380 reads (32%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as COSV56299938; called by muse, mutect2
- PCDH8 | c.2609G>A p.R870Q | Missense Mutation (SNP) | VAF 89/259 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.468); catalogued as rs1407354737; called by muse, mutect2, varscan2
- PCDHA3 | c.458C>A p.S153* | Nonsense Mutation (SNP) | VAF 92/291 reads (32%) | catalogued as COSV65365425; called by muse, mutect2, varscan2
- PDPR | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 32/420 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753821381; called by muse, mutect2
- PRTG | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.403); catalogued as rs749042100, COSV66839271; called by muse, mutect2, varscan2
- PRUNE2 | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 59/161 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV65046606; called by muse, mutect2, varscan2
- PTPN2 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs1254988153; called by muse, mutect2
- R3HDM2 | c.2045C>G p.S682C | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61291101, COSV61294284; called by muse, mutect2
- RBBP5 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 24/120 reads (20%) | catalogued as COSV52706459; called by muse, mutect2, varscan2
- RBM18 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.05); catalogued as COSV101313800, COSV69874339; called by muse, mutect2, varscan2
- RCC1L | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 132/353 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.374); catalogued as rs781910319; called by muse, mutect2
- RERE | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 103/271 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs1157900037, COSV61945030; called by muse, mutect2, varscan2
- SEPTIN14 | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs778731243, COSV66428415; called by muse, mutect2, varscan2
- SIRT2 | c.512C>A p.T171N | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs550825769; called by muse, mutect2, varscan2
- SPTA1 | c.6544G>C p.D2182H | Missense Mutation (SNP) | VAF 65/307 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs187749998, COSV63753555; called by muse, mutect2, varscan2
- TELO2 | c.1352C>T p.S451L | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs148873855; called by muse, mutect2, varscan2
- TINAGL1 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs200401314, COSV54698792; called by muse, mutect2, varscan2
- TLL1 | c.2647C>T p.H883Y | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.634); catalogued as rs1005207244; called by muse, mutect2
- TNXB | c.9943G>A p.V3315M (on ENST00000647633; = p.V3068M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 281/398 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs777978006, COSV64473259; called by muse, mutect2, varscan2
- TRAPPC9 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 165/473 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1184876472, COSV66900182; called by muse, mutect2, varscan2
- ZNF721 | c.424C>T p.Q142* (on ENST00000338977; = p.Q154* on NM_133474.4) | Nonsense Mutation (SNP) | VAF 116/343 reads (34%) | catalogued as COSV100167829; called by muse, mutect2, varscan2
- AC084756.2 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 32/61 reads (52%) | called by muse, mutect2, varscan2
- ANKRD42 | c.448C>G p.L150V | Missense Mutation (SNP) | VAF 107/328 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C6orf132 | c.3079G>T p.G1027C | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH12 | c.1210G>T p.G404C | Missense Mutation (SNP) | VAF 102/266 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDK12 | c.541_551del p.K181Qfs*15 | Frame Shift Del (DEL) | VAF 105/423 reads (25%) | called by mutect2, pindel, varscan2
- CEP295 | c.3068C>G p.S1023C | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- CFAP61 | c.2854G>A p.D952N | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- CIITA | c.2009G>A p.R670K | Missense Mutation (SNP) | VAF 128/559 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CYLC1 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- EARS2 | c.146T>G p.L49W | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHB6 | c.2530G>T p.D844Y | Missense Mutation (SNP) | VAF 174/455 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERBB3 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 128/407 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- FRMD7 | c.212A>T p.K71M | Missense Mutation (SNP) | VAF 39/58 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- HECTD4 | c.6583A>G p.T2195A | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- HELQ | c.2120G>C p.R707T | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HELZ | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 52/237 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- IGHV3-35 | c.318G>T p.R106S | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.75); called by muse, mutect2
- INTS9 | c.1931G>C p.R644T | Missense Mutation (SNP) | VAF 141/369 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- KDM4A | c.1413dup p.L472Tfs*6 | Frame Shift Ins (INS) | VAF 15/44 reads (34%) | called by mutect2, pindel, varscan2
- LATS2 | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 89/273 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MED14 | c.2910T>G p.N970K | Missense Mutation (SNP) | VAF 38/57 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- MTUS1 | c.3133G>T p.E1045* (on ENST00000262102 / NM_001363061.1; = p.E211* on NM_020749.4) | Nonsense Mutation (SNP) | VAF 43/153 reads (28%) | called by muse, mutect2, varscan2
- MYCBP2 | c.9433A>G p.I3145V (on ENST00000357337; = p.I3183V on NM_015057.5) | Missense Mutation (SNP) | VAF 125/165 reads (76%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- NCOR2 | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 73/203 reads (36%) | called by muse, mutect2, varscan2
- NR1H4 | c.1155del p.S385Rfs*5 (on ENST00000551379 / NM_001206993.2; = p.S371Rfs*5 on NM_005123.4) | Frame Shift Del (DEL) | VAF 39/123 reads (32%) | called by mutect2, pindel, varscan2
- NUP58 | c.389C>G p.S130* | Nonsense Mutation (SNP) | VAF 52/167 reads (31%) | called by muse, mutect2, varscan2
- OR14K1 | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 106/384 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR1L4 | c.923G>T p.R308I | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.201); called by muse, varscan2
- PCSK7 | c.1299C>A p.H433Q | Missense Mutation (SNP) | VAF 99/278 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PDCL3 | c.153G>A p.M51I | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PKHD1L1 | c.1730C>G p.S577C | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- PRDM5 | c.1783C>G p.H595D | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PRUNE2 | c.4018G>A p.D1340N | Missense Mutation (SNP) | VAF 88/242 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PSMG1 | c.457-1G>A p.X153_splice | Splice Site (SNP) | VAF 40/138 reads (29%) | called by mutect2, varscan2
- RIMS1 | c.4558C>T p.L1520F | Missense Mutation (SNP) | VAF 230/590 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RUSC1 | c.2144C>T p.S715L (on ENST00000368352 / NM_001105203.2; = p.S246L on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 133/493 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLC16A11 | c.878C>T p.A293V (on ENST00000308009; = p.A269V on NM_153357.3) | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- SMC3 | c.1808C>T p.T603I | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- SPATS2L | c.1108C>G p.L370V | Missense Mutation (SNP) | VAF 104/320 reads (33%) | SIFT tolerated (0.91); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- SPTA1 | c.2462T>A p.L821H | Missense Mutation (SNP) | VAF 93/353 reads (26%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- SRSF4 | c.596G>A p.R199K | Missense Mutation (SNP) | VAF 63/223 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TMEM215 | c.557G>C p.R186T | Missense Mutation (SNP) | VAF 113/328 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- TPCN1 | c.2307C>A p.S769R | Missense Mutation (SNP) | VAF 68/219 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- TTC6 | c.1343C>G p.S448* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2
- UTP20 | c.7264-1G>A p.X2422_splice | Splice Site (SNP) | VAF 37/101 reads (37%) | called by muse, mutect2, varscan2
- ZC3H7A | c.149G>C p.G50A | Missense Mutation (SNP) | VAF 52/225 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFAND5 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ZFP30 | c.622C>A p.H208N | Missense Mutation (SNP) | VAF 76/255 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF451 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 37/116 reads (32%) | called by muse, mutect2, varscan2
- ZNF529 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACO1 | c.2487C>G p.L829= | Silent (SNP) | VAF 62/169 reads (37%) | catalogued as COSV59381048; called by muse, mutect2, varscan2
- AMDHD2 | c.900C>T p.G300= | Silent (SNP) | VAF 36/896 reads (4%) | catalogued as rs778540242; called by muse, mutect2
- CCDC124 | c.258G>A p.A86= | Silent (SNP) | VAF 166/293 reads (57%) | called by muse, mutect2, varscan2
- CTSS | c.552C>T p.F184= | Silent (SNP) | VAF 75/300 reads (25%) | catalogued as rs587642423, COSV64567021; called by muse, mutect2, varscan2
- EIF3A | c.2964C>T p.S988= | Silent (SNP) | VAF 132/364 reads (36%) | catalogued as COSV64960682; called by muse, mutect2, varscan2
- ELFN1 | c.780C>G p.V260= | Silent (SNP) | VAF 86/223 reads (39%) | catalogued as COSV101300249; called by muse, mutect2, varscan2
- ELP6 | c.249C>T p.F83= | Silent (SNP) | VAF 54/179 reads (30%) | called by muse, mutect2, varscan2
- FAM53B | c.294C>T p.I98= | Silent (SNP) | VAF 67/194 reads (35%) | called by muse, mutect2, varscan2
- FCRL3 | c.1395G>A p.V465= | Silent (SNP) | VAF 44/172 reads (26%) | called by muse, mutect2, varscan2
- FDX2 | c.516C>T p.I172= | Silent (SNP) | VAF 233/416 reads (56%) | catalogued as rs1394254913; called by muse, mutect2, varscan2
- GNAS | c.1584C>G p.L528= | Silent (SNP) | VAF 186/516 reads (36%) | catalogued as rs1260949887; called by muse, mutect2, varscan2
- GRIP1 | c.1650G>A p.T550= (on ENST00000359742 / NM_001379345.1; = p.T498= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 103/271 reads (38%) | catalogued as rs1369161246, COSV54022542, COSV54038894; called by muse, mutect2, varscan2
- HYDIN | c.1773T>C p.N591= | Silent (SNP) | VAF 75/242 reads (31%) | called by muse, mutect2, varscan2
- IQCN | c.3156C>T p.I1052= | Silent (SNP) | VAF 92/357 reads (26%) | catalogued as rs576833251; called by muse, mutect2, varscan2
- ITGA9 | c.663C>T p.I221= | Silent (SNP) | VAF 68/215 reads (32%) | called by muse, mutect2, varscan2
- L3MBTL4 | c.1050G>A p.P350= | Silent (SNP) | VAF 51/143 reads (36%) | catalogued as rs267605237; called by muse, mutect2, varscan2
- MFSD4A | c.1065C>T p.F355= | Silent (SNP) | VAF 73/298 reads (24%) | catalogued as COSV65657177; called by muse, mutect2, varscan2
- MRPS30 | c.552C>T p.L184= | Silent (SNP) | VAF 47/123 reads (38%) | catalogued as rs1449062417; called by muse, mutect2, varscan2
- MYO3B | c.3606G>T p.G1202= | Silent (SNP) | VAF 31/94 reads (33%) | called by muse, mutect2, varscan2
- NSMCE2 | c.399G>A p.L133= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs1466906535; called by muse, mutect2, varscan2
- PCDHA11 | c.1626G>A p.P542= | Silent (SNP) | VAF 315/826 reads (38%) | catalogued as rs782392672, COSV56519949; called by muse, mutect2, varscan2
- PNPLA3 | c.657C>T p.L219= | Silent (SNP) | VAF 117/337 reads (35%) | called by muse, mutect2, varscan2
- PPWD1 | c.1113G>C p.L371= | Silent (SNP) | VAF 40/108 reads (37%) | called by muse, mutect2, varscan2
- PTPRH | c.3069C>T p.G1023= | Silent (SNP) | VAF 85/176 reads (48%) | catalogued as rs369061024; called by muse, mutect2, varscan2
- RPL3 | c.48C>T p.F16= | Silent (SNP) | VAF 99/261 reads (38%) | called by muse, mutect2, varscan2
- SALL3 | c.948C>T p.A316= | Silent (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2, varscan2
- SCN5A | c.2007C>T p.L669= | Silent (SNP) | VAF 70/217 reads (32%) | called by muse, mutect2, varscan2
- SNED1 | c.1428C>T p.N476= | Silent (SNP) | VAF 94/271 reads (35%) | catalogued as rs368791923; called by muse, mutect2, varscan2
- SSC5D | c.1041C>T p.C347= | Silent (SNP) | VAF 135/230 reads (59%) | catalogued as rs1336519069, COSV101046504; called by muse, mutect2, varscan2
- TMIGD1 | c.64C>T p.L22= | Silent (SNP) | VAF 49/60 reads (82%) | called by muse, mutect2, varscan2
- VWF | c.126C>T p.F42= | Silent (SNP) | VAF 155/429 reads (36%) | catalogued as rs200710351, COSV99778350; called by muse, mutect2, varscan2
- WDR74 | c.1122G>A p.R374= | Silent (SNP) | VAF 77/180 reads (43%) | called by muse, mutect2, varscan2
- WNT2 | c.42G>A p.L14= | Silent (SNP) | VAF 69/194 reads (36%) | catalogued as COSV99625671; called by muse, varscan2
- ZMYND11 | c.135C>T p.H45= | Silent (SNP) | VAF 51/132 reads (39%) | catalogued as rs368308575; called by muse, mutect2, varscan2
- ZNF529 | c.609A>G p.Q203= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs200704899; called by muse, mutect2, varscan2
- ZNF791 | c.1152C>T p.Y384= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs182973227; called by muse, mutect2, varscan2
- ACTN4 | c.*166T>C | 3'UTR (SNP) | VAF 179/355 reads (50%) | catalogued as rs779624869; called by muse, mutect2, varscan2
- CRIP3 | chr6:43305752 C>T | 3'Flank (SNP) | VAF 82/196 reads (42%) | catalogued as COSV99240359; called by muse, mutect2, varscan2
- FMO1 | c.1184-69C>A | Intron (SNP) | VAF 23/72 reads (32%) | catalogued as rs1459684980; called by muse, mutect2, varscan2
- MSC-AS1 | n.344C>T | RNA (SNP) | VAF 107/330 reads (32%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.899C>T | RNA (SNP) | VAF 197/504 reads (39%) | catalogued as rs1457579821; called by muse, mutect2, varscan2
- PEX19 | c.816+32T>A | Intron (SNP) | VAF 211/409 reads (52%) | called by muse, mutect2, varscan2
- PSG4 | c.65-608C>T | Intron (SNP) | VAF 60/269 reads (22%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.1642G>A | RNA (SNP) | VAF 29/92 reads (32%) | called by muse, mutect2, varscan2
- SGSM3 | c.2172+73G>A | Intron (SNP) | VAF 52/147 reads (35%) | catalogued as COSV50651911; called by muse, mutect2, varscan2
- SLC2A14 | c.-59G>C | 5'UTR (SNP) | VAF 25/76 reads (33%) | called by muse, mutect2, varscan2
- SLC7A7 | c.-180-141G>A | Intron (SNP) | VAF 126/376 reads (34%) | catalogued as rs1288257184; called by muse, mutect2, varscan2
- SPAG6 | c.-13C>T | 5'UTR (SNP) | VAF 49/128 reads (38%) | catalogued as rs909856066; called by muse, mutect2, varscan2
- SSPOP | n.11684C>T | RNA (SNP) | VAF 79/221 reads (36%) | called by muse, mutect2, varscan2
- SSPOP | n.13078G>A | RNA (SNP) | VAF 123/309 reads (40%) | catalogued as rs748253553; called by muse, mutect2, varscan2
- STRA6 | c.-15-161G>C | Intron (SNP) | VAF 52/169 reads (31%) | called by muse, mutect2, varscan2
- TENT5A | c.-242A>T | 5'UTR (SNP) | VAF 116/294 reads (39%) | called by muse, mutect2, varscan2
- TRIO | c.7632+24C>T | Intron (SNP) | VAF 33/96 reads (34%) | called by mutect2, varscan2
